Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3882, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3882-01A (Primary Tumor).

Diagnosis

The material at hand displays a moderately differentiated adenocarcinoma of the colon with characteristic, mainly tubular tumor cell groups and clear nucleoplasmic adjustment as well as infiltration of the muscularis, consistent with a classification according to p T 2 and vascular infiltration (L1, V1). In relation to the resection margins, the margins are free, separated in the mucous membrane area by mucosa, submucosa and muscularis.

Tumor formula summary:

ICDO-DA-M 8140/3

G2

p T 2, L1, V1, p N 0.

Source: NCI Genomic Data Commons file 116989c3-3733-46c4-9a25-0abf59897332 (TCGA-AG-3882.FCD411F6-CE88-40A4-B734-575D5CA3DC02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).